Somatic mutation profile of tumor specimen TCGA-09-1672-01A (aliquot TCGA-09-1672-01A-01W-0633-09) from TCGA case TCGA-09-1672, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 78.2 years (28,556 days).
Specimen TCGA-09-1672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8420c628-bba5-4488-9c32-1d48c4e2383c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-1672-10A (Blood Derived Normal), aliquot TCGA-09-1672-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/169c2da5-cdb6-4774-8dce-d9a5d1052d71

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLIP2 | c.787G>C p.A263P | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56286407; called by muse, mutect2, varscan2
- COL1A2 | c.3277G>T p.G1093C | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51966275, COSV99799787; called by muse, mutect2, varscan2
- DYNC1H1 | c.12200C>G p.T4067S | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV64142407, COSV64142632; called by muse, mutect2, varscan2
- EIF5AL1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs928720295, COSV73123170; called by muse, mutect2, varscan2
- HTR6 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs755046439, COSV53877429; called by muse, mutect2, varscan2
- IL17RD | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV56334852, COSV56342947; called by muse, mutect2, varscan2
- MARCHF4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 81/351 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs367784136, COSV99814011; called by muse, mutect2, varscan2
- PCDHGB5 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV54035712; called by muse, mutect2, varscan2
- SCN5A | c.4018G>A p.V1340I (on ENST00000333535 / NM_198056.3; = p.V1339I on NM_000335.5) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199473605, CM100703, COSV61128014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRGAP2 | c.1801C>T p.R601W (on ENST00000624873 / NM_001170637.4; = p.R602W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369067812; called by muse, mutect2, varscan2
- TIE1 | c.1923dup p.S642Qfs*58 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as rs747980938; called by mutect2, varscan2
- ZNF142 | c.4868C>T p.P1623L (on ENST00000411696 / NM_001379660.1; = p.P1423L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs374493212; called by muse, mutect2, varscan2
- ARHGAP30 | c.928dup p.A310Gfs*2 | Frame Shift Ins (INS) | VAF 5/55 reads (9%) | called by pindel, varscan2
- FLG2 | c.6521del p.G2174Efs*228 | Frame Shift Del (DEL) | VAF 458/1309 reads (35%) | called by mutect2, pindel, varscan2
- KIF26B | c.3847A>T p.S1283C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- PI4K2B | c.810del p.R271Gfs*23 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- PNN | c.1207del p.Q403Rfs*3 | Frame Shift Del (DEL) | VAF 37/122 reads (30%) | called by mutect2, pindel, varscan2
- FOXO4 | c.1110C>T p.L370= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV58576488; called by muse, varscan2
- IPO7 | c.3108G>A p.G1036= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV65685218, COSV65687094; called by muse, mutect2, varscan2
- LIG3 | c.1695C>T p.D565= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99252938; called by muse, mutect2
- MTG2 | c.1116G>A p.A372= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs778978065, COSV63694129; called by muse, mutect2, varscan2
- WDR49 | c.1776C>T p.C592= (on ENST00000308378 / NM_001366158.1; = p.C933= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as COSV57718044; called by muse, mutect2, varscan2
